Somatic mutation profile of tumor specimen 0DII46 from CCDI case PBBVMZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,675 days).
Specimen 0DII46: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 062c6f5c-8b0d-4475-b7e6-a5d7e5dec72b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII37 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e5dd83e-e689-4703-b743-918d43584d3e

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/1334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- ARHGEF40 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 44/656 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.649); catalogued as rs753025921, COSV53880445; called by muse, mutect2
- KLK6 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 58/642 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as rs1307080062; called by muse, mutect2
- MROH9 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 45/638 reads (7%) | catalogued as rs1447165676; called by muse, mutect2
- BLZF1 | c.329T>A p.L110H | Missense Mutation (SNP) | VAF 70/1208 reads (6%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- HSPH1 | c.2145G>A p.M715I | Missense Mutation (SNP) | VAF 71/1214 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MEP1A | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 60/990 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RALGAPA2 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 29/1143 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
